Gene-level copy-number profile of tumor specimen ALCH-B3F0-TTP1-A from ALCHEMIST case ALCH-B3F0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,072 days).
Specimen ALCH-B3F0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f85f1f87-ee45-4cdd-8212-bab14989b459.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3F0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/def3b646-d255-4c55-bc9d-d12b917009e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,477; copy number 1: 12,437; copy number 2: 42,158; copy number 3: 2,268; copy number 4: 22; copy number 5: 36; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 1,418 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,201,518–8,215,210, 1 gene (within-gene range 0–3): LINC01714.
- chr1:8,218,190–8,220,529, 1 gene: AL358876.2.
- chr1:20,719,731–20,733,952, 2 genes: SH2D5, AL663074.1.
- chr2:24,789,734–24,793,382, 1 gene (within-gene range 0–2): PTRHD1.
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr6:37,507,348–37,535,616, 1 gene: LINC02520.
- chr6:85,731,371–86,087,134, 8 genes: AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1, AL450338.2, RNU4-12P, RPL7P27.
- chr7:5,556,731–5,606,655, 3 genes (within-gene range 0–1): AC006483.2, AC006483.1, FSCN1.
- chr7:62,275,361–63,088,261, 5 genes: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3.
- chr8:43,493,937–46,028,892, 9 genes: AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1, AC118650.1.
- chr8:140,505,813–140,635,633, 5 genes: AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2.
- chr9:125,200,542–125,257,071, 3 genes: RABEPK, HSPA5, AL354710.2.
- chr9:125,263,845–125,264,090, 1 gene (within-gene range 0–1): AL354710.1.
- chr9:137,838,419–138,179,774, 7 genes (within-gene range 0–3): MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2.
- chr10:5,498,697–5,526,771, 4 genes: CALML5, CALML3-AS1, CALML3, AL732437.1.
- chr10:32,511,336–32,511,737, 1 gene: C1DP1.
- chr10:38,356,380–42,281,819, 19 genes: HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr10:94,646,364–95,168,425, 14 genes: CTBP2P2, CYP2C18, AL583836.1, CYP2C19, MTND4P19, CYP2C58P, RPL7AP52, CYP2C9, MTND4P20, CYP2C59P, CYP2C60P, AL359672.1, CYP2C8, AL157834.4.
- chr11:48,579,436–48,908,946, 8 genes: OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:54,591,480–54,725,816, 11 genes: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:70,467,856–71,568,934, 22 genes (within-gene range 0–2): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1.
- chr11:76,137,315–76,137,731, 1 gene (within-gene range 0–2): AP002340.1.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr12:109,553,715–109,833,436, 8 genes: MMAB, RNU4-32P, MVK, RN7SKP250, FAM222A, FAM222A-AS1, TRPV4, MIR4497.
- chr14:18,333,726–21,643,578, 197 genes (broad region; genes not listed).
- chr14:67,441,855–67,441,930, 1 gene: MIR5694.
- chr15:25,170,723–25,250,940, 44 genes (within-gene range 0–3): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:64,671,263–64,719,602, 5 genes (within-gene range 0–2): RNU6-549P, OAZ2, AC100830.3, AC100830.2, AC100830.1.
- chr16:46,789,898–47,035,385, 9 genes (within-gene range 0–1): AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2.
- chr17:142,789–386,254, 5 genes (within-gene range 0–2): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1.
- chr17:16,342,534–16,492,193, 13 genes (within-gene range 0–2): CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:67,019,934–67,056,797, 3 genes (within-gene range 0–2): AC005544.1, AC005544.2, CACNG1.
- chr18:37,273,706–37,276,572, 1 gene (within-gene range 0–1): AC090386.1.
- chr19:7,595,863–24,163,425, 891 genes (broad region; genes not listed).
- chr19:43,401,496–43,418,597, 1 gene: TEX101.
- chr19:57,668,935–58,605,223, 88 genes (broad region; genes not listed).
- chr20:3,190,350–3,239,559, 3 genes: DDRGK1, ITPA, SLC4A11.
- chr20:31,440,632–31,645,006, 14 genes: DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2.
- chr20:64,047,582–64,072,347, 3 genes (within-gene range 0–2): SOX18, TCEA2, AL355803.1.
- chr22:41,367,333–41,399,326, 2 genes: TEF, RNU6-495P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 37 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:77,420,412–77,534,110, 3 genes, copy number 5: HMG20A, AC090984.1, AC046168.1.
- chr16:2,339,150–2,426,699, 1 gene, copy number 6 (within-gene range 2–6): ABCA17P.
- chr20:62,633,681–63,216,139, 33 genes, copy number 5: AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056, HAR1B, AL096828.4, HAR1A, AL096828.2, AL096828.1, MIR124-3, YTHDF1.

Autosomal genes at a single copy (total copy number 1): 10,914. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
